Gene-level copy-number profile of tumor specimen TCGA-BC-A217-01A from TCGA case TCGA-BC-A217, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 75.0 years (27,411 days).
Specimen TCGA-BC-A217-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.91a97e66-0120-439d-94c7-662401f4e587.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BC-A217-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cd316c5c-c742-4aba-8064-a63801ec177c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,654; copy number 2: 5,757; copy number 3: 17,517; copy number 4: 29,364; copy number 5: 3,468; copy number 6: 290; copy number 7: 1,233; copy number 8: 182; copy number 9: 4; copy number 10: 29; copy number 12: 78; copy number 13: 2; copy number 14: 47; copy number 17: 73; copy number 32: 111.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BC-A217-01A-11D-A151-01): tumor purity 0.92, ploidy 3.48, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 344 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:146,050,441–148,288,951, 67 genes, copy number 17 (broad region; genes not listed).
- chr1:148,295,180–148,344,638, 6 genes, copy number 17: LINC02806, AC245100.1, AC245100.5, Y_RNA, MIR5087, RNVU1-21.
- chr1:149,111,304–152,445,456, 168 genes, copy number 10–32 (within-gene range 7–32) (broad region; genes not listed).
- chr1:160,537,073–161,470,523, 56 genes, copy number 12 (within-gene range 3–12): AL138930.1, CD84, SLAMF1, SETP9, AL121985.1, CD48, SLAMF7, AL121985.3, AL121985.2, LY9, CD244, PPIAP37, ITLN1, AL354714.2, AL354714.3, AL354714.1, AL354714.4, ITLN2, F11R, AL591806.2, GLRX5P2, TSTD1, USF1, ARHGAP30, NECTIN4, NECTIN4-AS1, KLHDC9, PFDN2, NIT1, DEDD, AL591806.1, UFC1, AL590714.1, USP21, PPOX, B4GALT3, ADAMTS4, NDUFS2, FCER1G, APOA2, TOMM40L, MIR5187, NR1I3, PCP4L1, MPZ, SDHC, CFAP126, AL592295.6, RRM2P2, AL592295.4, AL592295.5, RNU6-481P, AL592295.3, AL592295.1, AL592295.2, AL831711.1.
- chr1:171,485,551–173,612,772, 41 genes, copy number 10–12 (within-gene range 5–12): PRRC2C, MYOCOS, MYOC, PFN1P1, RPL4P3, VAMP4, Z98751.1, Z98751.3, Z98751.2, AL135931.1, EEF1AKNMT, AL031864.1, AL031864.2, DNM3, DNM3-IT1, DNM3OS, MIR214, MIR3120, MIR199A2, AL137157.1, RNU6-157P, PIGC, C1orf105, SUCO, RNU6-693P, FASLG, SLC25A38P1, Z98043.1, AL031599.1, AIMP1P2, Z97198.1, TNFSF18, GOT2P2, AL022310.1, TNFSF4, AL645568.2, AL645568.1, PRDX6-AS1, PRDX6, SLC9C2, AL139142.1.
- chr16:70,802,084–71,230,722, 4 genes, copy number 9 (within-gene range 3–9): HYDIN, RNU6ATAC25P, AC138625.2, AC138625.1.
- chr17:66,835,117–66,895,572, 2 genes, copy number 13: CACNG5, RNA5SP446.

Autosomal genes at a single copy (total copy number 1): 1,654. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
